CCDI case PBBSMY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Meningiomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e9c3ba3e-acde-4bd3-9e11-6b0e4d1895c0

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Meningioma, malignant: ICD-O-3 morphology code: 9530/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.4 years (5,255 days).

Biospecimens (4 samples)
- Samples 0DFSQM, 0DFSSX (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFSS3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFUJL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
